Surgical pathology report (de-identified scan), TCGA case TCGA-06-6391, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6391-01A (Primary Tumor).

[page 1 of 4]
CLINICAL HISTORY

[REDACTED] has past history of [REDACTED] with [REDACTED] carcinoma diagnosed on [REDACTED] with currently active disease. Patient experiences headache, dysarthria, swallowing difficulty, and nausea and vomiting. On imaging, there is a large central necrotic area with enhancement with smaller satellite lesions in the cerebellar hemisphere; lesion may have been present since [REDACTED]

OPERATIVE DIAGNOSES

[REDACTED] Right cerebella tumor.
Operation/Specimen: A: Brain, biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, cerebellum, excisional biopsy:
1. ~~Glioblastoma~~.
2. MIB-1 proliferation index: 20%.
See Microscopy Description and Comment.

COMMENT

The sections are portions of cerebellum in which the white matter is heavily infiltrated by an astrocytic neoplastic proliferation that has nuclear atypia, mitotic figures, and microvascular cellular proliferation with focal vascular necrosis and thrombosis. There is focal nuclear tumor karyorrhexis (necrosis). There is not carcinoma. The neoplasm is glioblastoma (WHO IV).
Electronically Signed Out

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

[page 2 of 4]
[REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

A slide was examined and tumor DNA was enriched by microdissection.

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2)

[page 3 of 4]
A slide was examined and tumor DNA was enriched by microdissection.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, biopsy: Undifferentiated neoplasm, probably high grade, consistent

with primary brain tumor. 1 block + touch prep + crush prep. [REDACTED]

Telepathology consultation with [REDACTED]

Frozen section performed at [REDACTED]

[REDACTED] and called to the Physician of record.

GROSS DESCRIPTION

A.

Brain, biopsy:

SITE: Right cerebellar tumor.

[page 4 of 4]
FIXATIVE: Formalin. TYPE: biopsy. NO. PIECES: Several. SIZE/VOL:
Aggregate
to 1.5 x 1.0 x 0.3 cm. CASSETTES: A1 frozen section remnant, A2 all
remaining tissue. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates heavy gliofibrillogenesis
by the
neoplastic cells. About one third of neoplastic cells heavily over
expresses
the p53 protein. With the MIB-1 there is a proliferation index of
about 20%
in the more active areas.

ICD-9(s):
237.5 237.5

[REDACTED]

Histo Data

Part A: Brain, biopsy

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
EGFR VIII-slides x 1	2	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT-slides x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	
P53DO7 x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file c27ec220-93ec-4abd-b13f-480d1bff131d (TCGA-06-6391.BFBD13EA-6F58-4B40-9E5A-85DB0D9CD8D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).